Gene-level copy-number profile of tumor specimen ALCH-B0DY-TTP1-A from ALCHEMIST case ALCH-B0DY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.4 years (26,074 days).
Specimen ALCH-B0DY-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c30d3be3-387c-4c25-b4cf-4b882c5538a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0DY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8044b02d-002e-4657-9c51-02da2ea7b04e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 15,623; copy number 2: 41,284; copy number 3: 1,092; copy number 4: 850; copy number 5: 2; copy number 6: 1; copy number 8: 1; copy number 11: 1; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,732,880–20,733,952, 1 gene: AL663074.1.
- chr1:62,194,849–62,212,328, 3 genes: L1TD1, AL162739.1, Y_RNA.
- chr1:143,541,768–143,720,644, 6 genes: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr1:143,929,994–144,068,350, 3 genes (within-gene range 0–1): RPL22P5, FAM72C, SRGAP2D.
- chr2:8,666,636–8,681,864, 1 gene (within-gene range 0–2): ID2-AS1.
- chr2:15,801,747–15,810,877, 1 gene: AC113608.1.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–1): IGKV2D-14.
- chr2:90,309,230–90,315,836, 2 genes: AC233263.2, IGKV1OR2-118.
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–1): AC233266.1, AC233266.2, AC116050.1.
- chr2:91,674,857–91,685,884, 2 genes: RNA5SP100, DRD5P1.
- chr3:75,370,448–75,422,143, 5 genes (within-gene range 0–1): OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P.
- chr3:75,435,232–75,538,029, 2 genes (within-gene range 0–1): LINC02018, ENPP7P2.
- chr5:160,187,367–160,238,735, 2 genes: FABP6, FABP6-AS1.
- chr5:160,326,693–160,370,641, 2 genes (within-gene range 0–1): AC112191.3, C1QTNF2.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr9:123,485,529–123,485,622, 1 gene (within-gene range 0–2): MIR7150.
- chr11:73,308,276–73,397,474, 3 genes (within-gene range 0–1): ARHGEF17, RELT, AP000763.4.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr13:111,588,201–111,672,608, 2 genes: AL359649.1, LINC02337.
- chr13:112,313,467–112,331,225, 2 genes: LINC01043, LINC01044.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:91,232,532–91,253,925, 2 genes (within-gene range 0–1): GPR68, AL135818.1.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–1): RNU6-1191P.
- chr17:2,720,801–2,723,947, 1 gene: AC005696.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,597,691–105,626,066, 2 genes, copy number 5–8 (within-gene range 3–8): IGHE, IGHG4.
- chr14:105,639,559–105,644,790, 1 gene, copy number 11 (within-gene range 4–11): IGHG2.
- chr14:105,647,924–105,649,057, 1 gene, copy number 6: COPDA1.
- chr17:48,382,371–48,382,586, 1 gene, copy number 5 (within-gene range 4–5): U3.
- chr20:64,290,187–64,313,132, 2 genes, copy number 16: CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 12,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
